Somatic mutation profile of tumor specimen 0DF2DI from CCDI case PBBRPX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.1 years (1,116 days).
Specimen 0DF2DI: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f8f9fa10-d2a5-4391-8bca-add0c4c06376.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DF2DJ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7cdc8e2d-a4c8-47ef-9a1a-9aae23ea79a2

The open-access MAF lists 6 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Silent 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1309G>T p.G437C (on ENST00000288602 / NM_001374244.1; = p.G397C on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 303/984 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs760702929, COSV99967256; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH17 | c.284G>A p.R95Q | Missense Mutation (SNP) | VAF 285/723 reads (39%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as rs757908453; called by muse, mutect2, varscan2
- NCF1 | c.530T>G p.L177R | Missense Mutation (SNP) | VAF 80/1620 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); called by muse, mutect2
- OR2T12 | c.954G>A p.R318= | Silent (SNP) | VAF 193/579 reads (33%) | catalogued as rs756652987, COSV58778477, COSV58780094; called by muse, mutect2, varscan2
- PI4KA | c.5964C>T p.L1988= | Silent (SNP) | VAF 276/1104 reads (25%) | catalogued as rs772826241, COSV99745647; called by muse, mutect2, varscan2
- CPED1 | c.*16G>A | 3'UTR (SNP) | VAF 152/301 reads (50%) | called by muse, mutect2, varscan2
